Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A8ID, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A8ID-01A (Primary Tumor).

[page 1 of 3]
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

(A) RIGHT PELVIC LYMPH NODES:

METASTATIC CARCINOMA IN TWO OF FOURTEEN LYMPH NODES (2/14). (SEE COMMENT)

(B) LEFT PELVIC LYMPH NODES:

Five lymph nodes, no tumor present(0/5).

(C) ANTERIOR BLADDER NECK:

Supplemental report to follow.

(D) PROSTATE AND SEMINAL VESICLES:

Supplemental report to follow.

Entire report and diagnosis completed by .

COMMENT

The foci of metastatic carcinoma measure 1.0 and 3.0 mm. No extranodal extension is present.

*CLCE ICD-O-3
Adenocarcinoma, acinar 8140/1
path Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
JW 11/24/13*

GROSS DESCRIPTION

(A) RIGHT PELVIC LYMPH NODES – Fibroadipose tissue, 4.0 x 4.0 x 2.0 cm. Multiple lymph nodes are identified, ranging from 0.1 x less than 0.1 x less than 0.1 cm to 2.2 x 0.8 x 0.5 cm.

SECTION CODE: A1-A3, each containing four possible lymph nodes; A4, one lymph node, serially sectioned; A5, one lymph node, serially sectioned.

(B) LEFT PELVIC LYMPH NODES – Fibroadipose tissue, 3.0 x 3.0 x 1.5 cm. Five possible lymph nodes are identified ranging from 0.2 x 0.2 x 0.2 cm to 2.2 x 0.8 x 0.4 cm.

SECTION CODE: B1, one lymph node; B2, three possible lymph nodes; B3, one lymph node, serially sectioned; B4, remainder of fibroadipose tissue, entirely submitted.

(C) ANTERIOR BLADDER NECK – Supplemental report to follow.

(D) PROSTATE AND SEMINAL VESICLES – Supplemental report to follow.

CLINICAL HISTORY

Prostate cancer.

SNOMED CODES

T-C4600, M-Y1976

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

Start of ADDENDUM

[page 2 of 3]
Specimen Date/Time:

ADDENDUM

This modified report is being issued to provide additional information/results.

Addendum completed by

DIAGNOSIS

(C) ANTERIOR BLADDER NECK:

Smooth muscle and adipose tissue consistent with bladder neck tissue, no tumor present.

(D) PROSTATE AND SEMINAL VESICLES:

PROSTATIC ADENOCARCINOMA, GLEASON SCORE 9 (5+4) (SEE COMMENT).

MULTIFOCAL EXTRAPROSTATIC EXTENSION PRESENT.

TUMOR EXTENDING TO THE MARGIN OF RESECTION.

TUMOR INVADING RIGHT AND LEFT SEMINAL VESICLES AND PERIVESICULAR SOFT TISSUE.

VASCULAR/LYMPHATIC INVASION PRESENT.

SEE PREVIOUS REPORT FOR DIAGNOSIS OF PELVIC LYMPH NODES.

COMMENT

More than 90% of the prostate gland is involved by prostatic adenocarcinoma. The tumor measures 4.0 x 3.8 cm in the largest cross sectional dimension and it is present in the three cross sections and extensively in the apex and bases regions. The tumor exhibits multifocal extraprostatic extension. The tumor invades the intra and extraprostatic portions of the right seminal vesicle and the extraprostatic portion of the left seminal vesicle. Extensive invasion of perivesicular soft tissue is also present. The tumor extends in the apex (anterior and posterior) and posterior base region to the inked margin of resection). The added length of marginal involvement is 4.0 mm. Focal extension of tumor to the cauterized margin in other regions cannot be unequivocally established.

Please refer to the previous report for the diagnosis of the pelvic lymph nodes.

GROSS DESCRIPTION

(C) ANTERIOR BLADDER NECK – A portion of tan-gray tissue (4.4 x 1.7 x 0.8 cm). No orientation provided. Submitted in toto in C1-C4.

(D) PROSTATE AND SEMINAL VESICLES – A specimen consisting of a prostate, attached right and left seminal vesicles and attached segments of right and left vasa deferentia.

The prostate gland (6.0 x 2.8 x 4.2 cm, 47 grams, post-fixation) has the usual shape. The soft tissue present along the left posterolateral aspect of the prostate appears more abundant than along the right side. Nodules are palpated on the right and left anterior surface of the prostate. Serial cross sections after fixation demonstrate firm areas consistent with tumor in the right and left anterior region of the prostate of the three cross sections.

[page 3 of 3]
Specimen Date/Time:

The seminal vesicles and segments of vasa deferentia are grossly free of tumor.

SECTION CODE: D1-D4, right seminal vesicle and segment of right vas deferens from the base towards the tip; D5-D8, left seminal vesicle and segment of left vas deferens from the base towards the tip; D9, D10, prostatic base, right border; D11-D16, prostatic base, right posterior border; D17-D26, prostatic base, central portion; D27, prostatic base, left border; D28-D30, prostatic base, left posterior border; D31, D32, apex anterior; D33, D34, apex left; D35-D39, apex posterior; D40-D41, apex right; D42-D55, sections of the three cross sections of the prostate according to specimen radiograph.

The anterior aspect of the prostate is inked in green, left surface in red, right surface in yellow and posterior surface in black.

SNOMED CODES

T-92000, M-Y1973

Entire report and diagnosis completed by:

-----END OF REPORT-----

Criteria:	10/23/2023	No

Source: NCI Genomic Data Commons file 2cd70c06-b96e-41a8-aa4c-4412f3490a8a (TCGA-KK-A8ID.51303D5A-8963-4A4E-8A30-8EB0CA6D9437.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).